Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8289, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8289-01A (Primary Tumor).

[page 2 of 6]
Microscopic Description	Diagnosis Details

[page 3 of 6]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Fundus Tumor size: 12 x 9 x 2.5 cm Tumor features: None specified Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Lesser omentum Lymph nodes: 11/11 positive for metastasis (Intraabdominal 11/11) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: mets to liver; HER2NEU 2+

[page 4 of 6]
Laterality		ID

[page 5 of 6]
Excision date		Case ID	

Source: NCI Genomic Data Commons file d18b18a1-0d5e-44e8-b9e1-04be51ae6306 (TCGA-BR-8289.35305FF8-448B-4C82-BF25-E75CF563DD18.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).